Somatic mutation profile of tumor specimen TCGA-23-1027-01A (aliquot TCGA-23-1027-01A-02W-0486-08) from TCGA case TCGA-23-1027, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 48.2 years (17,588 days).
Specimen TCGA-23-1027-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f135c44e-9dc7-4749-bf10-89437429a2b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-23-1027-10A (Blood Derived Normal), aliquot TCGA-23-1027-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/612340f7-cbde-4eb9-a32c-cca526bc3dec

The open-access MAF lists 49 somatic variants for this specimen: 42 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 37, Silent 7, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.592G>T p.E198* | Nonsense Mutation (SNP) | VAF 262/401 reads (65%) | hotspot (GDC flag); catalogued as rs1567551854, COSV52678088, COSV52771688, COSV53175941; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANTXR1 | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV58015443; called by muse, mutect2, varscan2
- ANXA5 | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV56639304; called by muse, mutect2, varscan2
- ARGFX | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); catalogued as COSV57681679, COSV57682208, COSV57682652; called by muse, mutect2, varscan2
- ATP5MF-PTCD1 | c.69G>C p.W23C | Missense Mutation (SNP) | VAF 179/500 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52855006; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.1595G>T p.G532V | Missense Mutation (SNP) | VAF 132/208 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV63245466; called by muse, mutect2, varscan2
- CASP1 | c.614A>T p.N205I (on ENST00000436863 / NM_033292.4; = p.N184I on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 291/671 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62056860; called by muse, mutect2, varscan2
- CCNF | c.658A>T p.T220S | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV99563448; called by muse, mutect2, varscan2
- CES5A | c.155T>C p.V52A | Missense Mutation (SNP) | VAF 71/125 reads (57%) | SIFT tolerated (0.77); PolyPhen benign (0.023); catalogued as COSV51867455; called by muse, mutect2, varscan2
- COL22A1 | c.2912A>G p.D971G | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.391); catalogued as rs1466561035, COSV57342815; called by muse, mutect2, varscan2
- DENND11 | c.1145A>G p.N382S | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs769944687, COSV72097701; called by muse, mutect2, varscan2
- EDRF1 | c.641A>G p.N214S | Missense Mutation (SNP) | VAF 61/85 reads (72%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs141672047; called by muse, mutect2, varscan2
- EDRF1 | c.2986G>T p.V996F (on ENST00000356792 / NM_001202438.2; = p.V962F on NM_015608.2) | Missense Mutation (SNP) | VAF 25/257 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as COSV61764605; called by muse, mutect2, varscan2
- EFHC1 | c.1070A>C p.E357A | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV64136642; called by muse, mutect2, varscan2
- GPR37 | c.1023G>C p.E341D | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58257547; called by muse, mutect2, varscan2
- GRIK2 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.917); catalogued as COSV59743204, COSV59744339; called by muse, mutect2, varscan2
- HACE1 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 125/183 reads (68%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.849); catalogued as COSV53502493; called by muse, mutect2, varscan2
- IFI44 | c.229A>G p.I77V | Missense Mutation (SNP) | VAF 90/165 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1032934571, COSV66074989; called by muse, mutect2, varscan2
- IQGAP3 | c.3883G>T p.E1295* | Nonsense Mutation (SNP) | VAF 26/150 reads (17%) | catalogued as rs550783446, COSV63252380; called by muse, mutect2, varscan2
- KCNA3 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as COSV63901966; called by muse, mutect2, varscan2
- KRT72 | c.1147A>C p.K383Q | Missense Mutation (SNP) | VAF 125/324 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53374814; called by muse, mutect2, varscan2
- LPIN2 | c.513G>C p.Q171H | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV55240747; called by muse, mutect2, varscan2
- NF1 | c.5588G>C p.G1863A (on ENST00000358273 / NM_001042492.3; = p.G1842A on NM_000267.3) | Missense Mutation (SNP) | VAF 101/147 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV62207272, COSV62212777; called by muse, mutect2, varscan2
- NLRP11 | c.2471C>T p.T824M | Missense Mutation (SNP) | VAF 97/263 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.129); catalogued as rs374529395; called by muse, mutect2, varscan2
- NR1H4 | c.205C>A p.P69T (on ENST00000551379 / NM_001206993.2; = p.P59T on NM_005123.4) | Missense Mutation (SNP) | VAF 189/319 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.347); catalogued as COSV99500323; called by muse, mutect2, varscan2
- NR1H4 | c.206C>A p.P69Q (on ENST00000551379 / NM_001206993.2; = p.P59Q on NM_005123.4) | Missense Mutation (SNP) | VAF 191/324 reads (59%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs919024638, COSV99500334; called by muse, mutect2, varscan2
- PLCG1 | c.896T>A p.V299D | Missense Mutation (SNP) | VAF 276/823 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99718706; called by muse, mutect2, varscan2
- PRX | c.2468C>T p.A823V | Missense Mutation (SNP) | VAF 48/412 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs780212559, COSV52530674; called by muse, mutect2, varscan2
- PTPN5 | c.1295C>T p.T432M | Missense Mutation (SNP) | VAF 119/195 reads (61%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.793); catalogued as rs928392312, COSV62124997; called by muse, mutect2, varscan2
- RIMS1 | c.4790G>A p.R1597Q | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1447666261, COSV53442622; called by muse, mutect2, varscan2
- SBDS | c.512A>T p.H171L | Missense Mutation (SNP) | VAF 144/416 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV55887948; called by muse, mutect2, varscan2
- SEC16B | c.1553G>C p.G518A | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as COSV57627074; called by muse, mutect2, varscan2
- UBR2 | c.4291G>A p.D1431N | Missense Mutation (SNP) | VAF 7/176 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV100867402; called by muse, mutect2
- WNK4 | c.3116C>G p.S1039C | Missense Mutation (SNP) | VAF 184/238 reads (77%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV55906141; called by muse, mutect2, varscan2
- WRN | c.2423A>T p.H808L | Missense Mutation (SNP) | VAF 64/106 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV99988708; called by muse, mutect2, varscan2
- ZAP70 | c.908A>G p.D303G | Missense Mutation (SNP) | VAF 95/236 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1490208855, COSV53855022; called by muse, mutect2, varscan2
- ZC3H4 | c.2498C>T p.P833L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.163); catalogued as rs1043772363, COSV53415319; called by muse, mutect2, varscan2
- ZNF48 | c.1216C>G p.L406V | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.16); PolyPhen benign (0.143); catalogued as rs376605302; called by muse, mutect2, varscan2
- FOLH1B | n.1254+2T>A | Splice Site (SNP) | VAF 51/143 reads (36%) | called by muse, mutect2, varscan2
- SLC24A1 | c.263dup p.K89* | Frame Shift Ins (INS) | VAF 4/48 reads (8%) | called by pindel, varscan2
- TTLL13P | c.802_824del p.A268Yfs*6 | Frame Shift Del (DEL) | VAF 32/153 reads (21%) | called by mutect2, pindel
- WASHC2C | c.3807C>G p.I1269M (on ENST00000336378; = p.I1248M on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AHNAK2 | c.3030A>G p.V1010= | Silent (SNP) | VAF 44/335 reads (13%) | catalogued as rs372805671; called by muse, mutect2, varscan2
- BAG6 | c.3345C>T p.A1115= (on ENST00000676571; = p.A1068= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/152 reads (40%) | catalogued as rs749692025, COSV52991835; called by muse, mutect2, varscan2
- CHRNB1 | c.1072C>T p.L358= | Silent (SNP) | VAF 88/134 reads (66%) | catalogued as COSV60140835; called by muse, mutect2, varscan2
- PPP6R2 | c.826C>T p.L276= | Silent (SNP) | VAF 58/99 reads (59%) | catalogued as COSV53294935; called by muse, mutect2, varscan2
- RXRB | c.753G>A p.K251= | Silent (SNP) | VAF 98/312 reads (31%) | catalogued as COSV63399796; called by muse, mutect2, varscan2
- SF3B1 | c.3633G>A p.L1211= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as COSV59217565; called by muse, mutect2, varscan2
- TTLL6 | c.2193C>A p.T731= (on ENST00000393382 / NM_001130918.3; = p.T424= on NM_173623.3) | Silent (SNP) | VAF 8/104 reads (8%) | catalogued as COSV100938090; called by muse, mutect2
